Somatic mutation profile of tumor specimen TCGA-VD-A8KK-01A (aliquot TCGA-VD-A8KK-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KK, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.6 years (19,958 days).
Specimen TCGA-VD-A8KK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4e67c4c-f7e2-4276-9f7d-3a7fe4994f43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KK-10A (Blood Derived Normal), aliquot TCGA-VD-A8KK-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27c6b3a0-6896-49ff-bc5e-d21c9f7580db

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 44/132 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAND1 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1310639632; called by muse, mutect2, varscan2
- FCRL1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs551893022, COSV63824514; called by muse, mutect2, varscan2
- FUS | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1480335769; called by muse, mutect2, varscan2
- IRAK3 | c.1087-2A>G p.X363_splice | Splice Site (SNP) | VAF 39/79 reads (49%) | catalogued as COSV99706593; called by muse, mutect2, varscan2
- VPREB3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs1341387207; called by muse, mutect2, varscan2
- BAP1 | c.371del p.P124Lfs*63 | Frame Shift Del (DEL) | VAF 15/24 reads (63%) | called by mutect2, pindel, varscan2
- CENPE | c.3113T>C p.I1038T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR7D4 | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- OVCH1 | c.3010A>G p.T1004A | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PDE4D | c.989C>G p.S330* (on ENST00000340635 / NM_001104631.2; = p.S194* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- ZNF527 | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP62 | c.639C>G p.T213= | Silent (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
